Somatic mutation profile of tumor specimen 0DC630 from CCDI case PBBLUX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 1.0 years (373 days).
Specimen 0DC630: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdfd877f-fd08-4008-8eba-db3f46c39829.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DC633 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38195e27-aa40-4a80-83de-6eccdab3746b

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 575/690 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- JAK1 | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 233/766 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs1306467125, COSV61096397; called by muse, mutect2, varscan2
- OR2L8 | c.734C>A p.T245N | Missense Mutation (SNP) | VAF 22/704 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV100594402; called by muse, mutect2
- SHROOM3 | c.4538C>T p.P1513L | Missense Mutation (SNP) | VAF 222/630 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs778822989, COSV56023691; called by muse, mutect2, varscan2
- ATAD3A | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 178/620 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- RAF1 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 49/791 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- POP5 | c.164-90C>T | Intron (SNP) | VAF 4/39 reads (10%) | catalogued as rs1027584590; called by muse, varscan2
